CGCI case BLGSP-71-06-00163 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e1812043-0c2d-44a1-b019-61b052f5bb08

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 25 years; Vital status: Dead; Days to death: 56 days.

Diagnoses (1)
1. B cell lymphoma, NOS: ICD-O-3 morphology code: 9591/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Lymph nodes of head, face and neck; Classification of tumor: primary; Year of diagnosis: 2015; Method of diagnosis: Incisional Biopsy; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 56 days; Burkitt lymphoma clinical variant: Immunodeficiency-associated, adult.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.

Follow-up (2 entries)
- Days to follow up: 0 days; Disease response: With Tumor; Karnofsky performance status: 80; ECOG performance status: 1.
- Follow-up contacts recording only the day: day -239, day 56.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Positive.
- Lactate Dehydrogenase 307 [Blood test normal range upper: 340].

Other clinical attributes
- Day -239: Risk factors: HIV/AIDS.
- Day -239: Comorbidities: HIV/AIDS.
- Day 0: Weight: 40 kg; Height: 160 cm; BMI: 15.6; CD4 count: 1053; Haart treatment indicator: Yes; HIV viral load: 47570.
- Day 0: Nadir CD4 count: 7.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-06-00163-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Other; Preservation method: Frozen; Days to sample procurement: 0 days; Method of sample procurement: Incisional Biopsy; Tissue collection type: Prospective.
  Slide BLGSP-71-06-00163-01A-01-S1-HE: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 30; Percent neutrophil infiltration: 0.
- Sample BLGSP-71-06-00163-01Z: Sample type: Tumor; Tissue type: Tumor.
  Slide BLGSP-71-06-00163-01-Ki67: Tissue microarray coordinates: D2,C3,A6.
  Slide BLGSP-71-06-00163-01-CD20: Tissue microarray coordinates: D2,C3,A6.
  Slide BLGSP-71-06-00163-01-BCL2: Tissue microarray coordinates: D2,C3,A6.
  Slide BLGSP-71-06-00163-01-BCL6: Tissue microarray coordinates: D2,C3,A6.
  Slide BLGSP-71-06-00163-01-CD10: Tissue microarray coordinates: D2,C3,A6.
  Slide BLGSP-71-06-00163-01-CD3: Tissue microarray coordinates: D2,C3,A6.
  Slide BLGSP-71-06-00163-01-HE-1: Tissue microarray coordinates: D2,C3,A6.
- Sample BLGSP-71-06-00163-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen; Days to sample procurement: 0 days; Method of sample procurement: Blood Draw; Tissue collection type: Prospective.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: With tumor; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease: Haart therapy prior to diagnosis: Yes; Haart therapy at diagnosis: Yes.
- Primary pathology: Histologic diagnosis: Unclassifiable B-cell lymphoma; Lymph nodes examined: No.
- Tests performed: LDH level: 307; Immunophenotypic analysis method: Immunohistochemistry.
- Treatments, Treatment: Treatment type: No Treatment.
